Somatic mutation profile of tumor specimen 1105262 (aliquot 7316UP-1206-1105262) from CPTAC case C234192, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Temporal lobe; Tumor grade: G4.
Specimen 1105262: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 25cdfb88-b980-4681-ba03-d63597c85a11.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105286 (Blood Derived Normal), aliquot 7316UP-386-1105286; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cdfc12d9-dca4-4346-92c6-583c77cc4f37

The open-access MAF lists 244 somatic variants for this specimen: 142 protein-altering or splice-affecting, 52 silent, 50 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 116, Silent 52, Intron 28, Frame Shift Del 9, 3'Flank 6, Splice Region 6, RNA 6, Nonsense Mutation 5, 5'UTR 5, Splice Site 4, 3'UTR 3, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.323G>A p.R108K | Missense Mutation (SNP) | VAF 7390/7635 reads (97%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519828, COSV51766433; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADCYAP1 | c.160G>A p.D54N | Missense Mutation (SNP) | VAF 174/406 reads (43%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs770809469; called by muse, mutect2, varscan2
- AKNA | c.1993G>A p.E665K | Missense Mutation (SNP) | VAF 241/602 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.019); catalogued as rs767572273, COSV56313253; called by muse, mutect2, varscan2
- AKR1B10 | c.742-7C>T | Splice Region (SNP) | VAF 126/486 reads (26%) | catalogued as rs766204329; called by muse, mutect2, varscan2
- AL592490.1 | c.923T>C p.I308T | Missense Mutation (SNP) | VAF 57/77 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs775154689; called by muse, mutect2, varscan2
- CCDC144A | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 133/347 reads (38%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs1365470382, COSV100501884; called by muse, mutect2, varscan2
- CR1 | c.5231G>A p.R1744Q | Missense Mutation (SNP) | VAF 79/222 reads (36%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.973); catalogued as rs55704352, COSV65456601; called by muse, varscan2
- DNAH10 | c.8485G>A p.E2829K (on ENST00000409039; = p.E2768K on NM_207437.3) | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.382); catalogued as rs1214085753; called by muse, mutect2, varscan2
- DOHH | c.406G>A p.G136S | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs922978504; called by muse, mutect2, varscan2
- EBPL | c.520G>A p.G174S | Missense Mutation (SNP) | VAF 84/146 reads (58%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.796); catalogued as rs200901347, COSV54431481; called by mutect2, varscan2
- EEA1 | c.1178C>T p.A393V | Missense Mutation (SNP) | VAF 92/130 reads (71%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as rs558859578; called by muse, mutect2, varscan2
- ERCC6L2 | c.1031C>T p.T344M | Missense Mutation (SNP) | VAF 119/267 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as rs1411881441; called by muse, mutect2, varscan2
- FRY | c.8420G>T p.G2807V | Missense Mutation (SNP) | VAF 22/258 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.101); catalogued as rs375326219; called by muse, mutect2
- GALC | c.1829A>G p.D610G | Missense Mutation (SNP) | VAF 52/139 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.379); catalogued as CM1515305; called by muse, mutect2, varscan2
- GK2 | c.117C>A p.H39Q | Missense Mutation (SNP) | VAF 50/140 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as COSV62627486; called by muse, mutect2, varscan2
- HMGB4 | c.185C>A p.A62D | Missense Mutation (SNP) | VAF 125/312 reads (40%) | SIFT tolerated (1); PolyPhen possibly damaging (0.653); catalogued as COSV53920739, COSV99595016; called by muse, mutect2, varscan2
- IGHA1 | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 180/462 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs753985358; called by muse, mutect2, varscan2
- IGHG2 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 205/550 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.153); catalogued as rs762234471; called by muse, mutect2, varscan2
- IGLL5 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 90/257 reads (35%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.4); catalogued as rs778472954; called by muse, mutect2, varscan2
- ITGA7 | c.2135+7G>A | Splice Region (SNP) | VAF 91/263 reads (35%) | catalogued as rs1026026295; called by muse, mutect2, varscan2
- ITGAM | c.1238G>A p.R413Q | Missense Mutation (SNP) | VAF 70/157 reads (45%) | SIFT tolerated (0.38); PolyPhen benign (0.18); catalogued as rs755777607, COSV54933096; called by muse, mutect2, varscan2
- KCNE1 | c.374C>T p.T125M | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs142511345, CM097709; ClinVar: not provided / likely benign / uncertain significance / conflicting interpretations of pathogenicity; called by mutect2, varscan2
- KRT86 | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 32/573 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs756000963; called by muse, mutect2
- LCN10 | c.536C>T p.A179V (on ENST00000474369 / NM_001368089.1; = p.A192V on NM_001001712.3) | Missense Mutation (SNP) | VAF 91/200 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.266); catalogued as rs751195542; called by muse, mutect2, varscan2
- MAPK15 | c.946C>T p.R316* | Nonsense Mutation (SNP) | VAF 100/282 reads (35%) | catalogued as rs782012920; called by muse, mutect2, varscan2
- MEIS2 | c.1228C>T p.P410S | Missense Mutation (SNP) | VAF 119/298 reads (40%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.01); catalogued as COSV54930885; called by muse, mutect2, varscan2
- MGST1 | c.298C>A p.P100T | Missense Mutation (SNP) | VAF 44/141 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs1036902850; called by muse, mutect2, varscan2
- MUC16 | c.12422G>T p.G4141V | Missense Mutation (SNP) | VAF 80/251 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.976); catalogued as rs1018086393; called by muse, mutect2, varscan2
- MUC5B | c.2960G>A p.R987H | Missense Mutation (SNP) | VAF 94/245 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.387); catalogued as rs1257475801, COSV71591412, COSV71594290; called by muse, mutect2, varscan2
- NEIL1 | c.283C>T p.R95C | Missense Mutation (SNP) | VAF 128/350 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as COSV61833127; called by muse, mutect2, varscan2
- NLRP5 | c.62+1G>A p.X21_splice | Splice Site (SNP) | VAF 89/280 reads (32%) | catalogued as rs199475763; ClinVar: not provided; called by muse, mutect2, varscan2
- NR2C2 | c.1659G>A p.M553I (on ENST00000393102; = p.M572I on NM_003298.5) | Missense Mutation (SNP) | VAF 56/112 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.026); catalogued as rs751428558; called by muse, mutect2, varscan2
- OR14A2 | c.64C>T p.R22W | Missense Mutation (SNP) | VAF 48/119 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.457); catalogued as rs779547225; called by muse, mutect2, varscan2
- OR6F1 | c.878G>A p.R293H | Missense Mutation (SNP) | VAF 57/160 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs372005274, COSV57467846; called by muse, mutect2, varscan2
- PDE10A | c.1105T>C p.Y369H | Missense Mutation (SNP) | VAF 72/164 reads (44%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.857); catalogued as COSV63050056; called by muse, mutect2
- PKD1 | c.9385G>A p.G3129S | Missense Mutation (SNP) | VAF 150/517 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.136); catalogued as rs1477230717; called by muse, mutect2, varscan2
- PLEC | c.2452C>T p.R818W (on ENST00000322810 / NM_201380.4; = p.R708W on NM_000445.5) | Missense Mutation (SNP) | VAF 283/653 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as rs781892147; called by muse, mutect2, varscan2
- PLXNA1 | c.4838C>T p.S1613F | Missense Mutation (SNP) | VAF 144/343 reads (42%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.993); catalogued as rs1402176857; called by muse, mutect2, varscan2
- POU1F1 | c.397G>C p.E133Q | Missense Mutation (SNP) | VAF 10/263 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV60155251; called by muse, mutect2
- PPARGC1B | c.1463C>T p.P488L | Missense Mutation (SNP) | VAF 181/482 reads (38%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.91); catalogued as rs753410582; called by muse, mutect2, varscan2
- PRDM9 | c.854A>G p.E285G | Missense Mutation (SNP) | VAF 18/400 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV57003650; called by muse, mutect2
- PTEN | c.122G>C p.R41T | Missense Mutation (SNP) | VAF 76/98 reads (78%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); catalogued as COSV64307058; called by muse, mutect2, varscan2
- RDH10 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 285/654 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as rs190882720, COSV53582156; called by muse, mutect2, varscan2
- RGS19 | c.465G>A p.V155= | Splice Region (SNP) | VAF 52/168 reads (31%) | catalogued as COSV58657885; called by muse, mutect2, varscan2
- RIC8A | c.8C>T p.P3L | Missense Mutation (SNP) | VAF 125/326 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs770203509; called by muse, mutect2, varscan2
- RPGR | c.1231C>T p.R411W | Missense Mutation (SNP) | VAF 168/199 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1267740350; called by muse, mutect2, varscan2
- SH3RF2 | c.1927G>A p.V643M | Missense Mutation (SNP) | VAF 66/146 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1182882077; called by muse, mutect2, varscan2
- SLC1A6 | c.110C>T p.T37M | Missense Mutation (SNP) | VAF 184/667 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.022); catalogued as rs1026402297, COSV55673390, COSV99693589; called by muse, mutect2, varscan2
- SSUH2 | c.58G>A p.A20T | Missense Mutation (SNP) | VAF 144/375 reads (38%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as rs147081374; called by muse, mutect2, varscan2
- STK32C | c.1119C>T p.N373= | Splice Region (SNP) | VAF 113/150 reads (75%) | catalogued as rs745931599; called by muse, mutect2, varscan2
- TCHH | c.5629G>A p.E1877K | Missense Mutation (SNP) | VAF 45/137 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.313); catalogued as COSV64277303; called by muse, mutect2, varscan2
- TFEC | c.515C>T p.P172L | Missense Mutation (SNP) | VAF 12/182 reads (7%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.838); catalogued as rs202236667, COSV55401677; called by muse, mutect2
- TIMD4 | c.239A>T p.K80M | Missense Mutation (SNP) | VAF 177/423 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as rs779272298; called by muse, mutect2, varscan2
- TOR4A | c.925C>T p.R309C | Missense Mutation (SNP) | VAF 159/319 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV62627636; called by muse, mutect2, varscan2
- TPTE | c.1268C>T p.S423L (on ENST00000618007 / NM_199261.4; = p.S405L on NM_199259.4) | Missense Mutation (SNP) | VAF 35/150 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.739); catalogued as rs570468666; called by muse, mutect2, varscan2
- WWC2 | c.2369C>G p.S790C | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.053); catalogued as rs1237914404; called by muse, mutect2, varscan2
- ZBTB39 | c.973G>A p.D325N | Missense Mutation (SNP) | VAF 143/360 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.434); catalogued as COSV55630225; called by muse, mutect2, varscan2
- ZNF804A | c.51C>G p.H17Q | Missense Mutation (SNP) | VAF 108/314 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs373088099; called by muse, mutect2, varscan2
- ZP2 | c.968C>T p.T323M | Missense Mutation (SNP) | VAF 120/245 reads (49%) | SIFT tolerated (0.27); PolyPhen benign (0.022); catalogued as rs558301595, COSV54814788; called by muse, mutect2, varscan2
- ABCA10 | c.1474G>A p.V492I | Missense Mutation (SNP) | VAF 86/235 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- ADAMTS16 | c.3344C>T p.P1115L | Missense Mutation (SNP) | VAF 120/278 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- ADRA2C | c.106G>T p.G36W | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- APBA3 | c.991C>T p.H331Y | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- ARFGEF3 | c.3235G>A p.V1079I | Missense Mutation (SNP) | VAF 38/75 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATF7IP | c.635G>A p.G212D | Missense Mutation (SNP) | VAF 101/220 reads (46%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BRAT1 | c.2339A>G p.D780G | Missense Mutation (SNP) | VAF 79/272 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CAPN2 | c.803G>A p.G268E | Missense Mutation (SNP) | VAF 115/430 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CENPB | c.350C>T p.T117I | Missense Mutation (SNP) | VAF 180/657 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- COL8A1 | c.2009del p.K670Rfs*16 | Frame Shift Del (DEL) | VAF 71/196 reads (36%) | called by mutect2, pindel, varscan2
- CSRNP1 | c.594C>A p.F198L | Missense Mutation (SNP) | VAF 147/449 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.249); called by muse, mutect2, varscan2
- DCUN1D3 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 160/379 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- DGAT2 | c.429+1G>A p.X143_splice | Splice Site (SNP) | VAF 88/230 reads (38%) | called by muse, mutect2, varscan2
- DGKQ | c.2821C>A p.P941T | Missense Mutation (SNP) | VAF 95/235 reads (40%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DNAH12 | c.3374G>T p.S1125I (on ENST00000351747; = p.S1148I on NM_001366028.2) | Missense Mutation (SNP) | VAF 124/357 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- DST | c.21967dup p.S7323Ffs*53 (on ENST00000361203 / NM_001374722.1; = p.S4996Ffs*22 on NM_015548.5) | Frame Shift Ins (INS) | VAF 26/85 reads (31%) | called by mutect2, pindel, varscan2
- EIF3E | c.581A>T p.E194V | Missense Mutation (SNP) | VAF 56/113 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- ETV6 | c.814C>T p.P272S | Missense Mutation (SNP) | VAF 100/236 reads (42%) | SIFT tolerated (0.52); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- FASLG | c.647C>A p.S216Y | Missense Mutation (SNP) | VAF 72/157 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- GIPR | c.634-3_634-1del p.X212_splice | Splice Site (DEL) | VAF 136/673 reads (20%) | called by mutect2, pindel, varscan2
- GLMN | c.1585+1G>A p.X529_splice | Splice Site (SNP) | VAF 10/179 reads (6%) | called by muse, mutect2
- GNAQ | c.397_400del p.K133Vfs*34 | Frame Shift Del (DEL) | VAF 32/149 reads (21%) | called by mutect2, pindel, varscan2
- GNL2 | c.2096A>G p.Y699C | Missense Mutation (SNP) | VAF 97/308 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GPX7 | c.70G>A p.D24N | Missense Mutation (SNP) | VAF 121/292 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- HBEGF | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 128/371 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IGFBP2 | c.869C>T p.T290I | Missense Mutation (SNP) | VAF 73/206 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IRAK2 | c.1712G>A p.R571K | Missense Mutation (SNP) | VAF 52/110 reads (47%) | SIFT tolerated (0.92); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- IWS1 | c.1801C>T p.Q601* | Nonsense Mutation (SNP) | VAF 66/135 reads (49%) | called by muse, mutect2, varscan2
- JMY | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNT2 | c.3370G>A p.V1124I | Missense Mutation (SNP) | VAF 123/335 reads (37%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- KHSRP | c.547G>A p.D183N | Missense Mutation (SNP) | VAF 113/357 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- KMT5C | c.708G>A p.R236= | Splice Region (SNP) | VAF 155/555 reads (28%) | called by muse, mutect2, varscan2
- LRP6 | c.2611G>A p.G871S | Missense Mutation (SNP) | VAF 143/362 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- LSAMP | c.19C>G p.P7A | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- MANSC1 | c.632C>G p.S211C | Missense Mutation (SNP) | VAF 94/228 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- MAP2 | c.4316C>T p.S1439F | Missense Mutation (SNP) | VAF 88/308 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, varscan2
- MCM7 | c.589T>C p.S197P | Missense Mutation (SNP) | VAF 91/331 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- MDN1 | c.15200C>A p.A5067D | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- MLXIPL | c.1432G>A p.G478R | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MUC12 | c.5347G>A p.G1783S (on ENST00000379442; = p.G1640S on NM_001164462.1) | Missense Mutation (SNP) | VAF 240/820 reads (29%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- MUC5B | c.15722C>T p.A5241V | Missense Mutation (SNP) | VAF 8/220 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.015); called by muse, mutect2
- MYOM3 | c.4159G>A p.G1387R | Missense Mutation (SNP) | VAF 176/417 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- NPHP1 | c.982G>T p.A328S (on ENST00000393272 / NM_207181.4; = p.A329S on NM_000272.5) | Missense Mutation (SNP) | VAF 203/509 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- NRIP3 | c.380G>A p.C127Y | Missense Mutation (SNP) | VAF 62/225 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- NUMA1 | c.2470G>A p.E824K | Missense Mutation (SNP) | VAF 174/367 reads (47%) | SIFT tolerated (0.64); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NWD1 | c.3553G>A p.A1185T | Missense Mutation (SNP) | VAF 93/331 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- OTOG | c.6338C>T p.S2113L | Missense Mutation (SNP) | VAF 50/130 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); called by muse, mutect2
- PCYT1A | c.123dup p.R42Tfs*8 | Frame Shift Ins (INS) | VAF 58/153 reads (38%) | called by mutect2, pindel, varscan2
- PHC2 | c.2279C>T p.S760F (on ENST00000257118 / NM_198040.2; = p.S225F on NM_004427.4) | Missense Mutation (SNP) | VAF 148/384 reads (39%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PLCH2 | c.628G>A p.V210M | Missense Mutation (SNP) | VAF 69/128 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLD1 | c.2095C>T p.Q699* | Nonsense Mutation (SNP) | VAF 69/190 reads (36%) | called by muse, mutect2, varscan2
- POLN | c.760del p.Q254Kfs*32 | Frame Shift Del (DEL) | VAF 61/172 reads (35%) | called by mutect2, pindel, varscan2
- RAD1 | c.455T>G p.V152G | Missense Mutation (SNP) | VAF 124/370 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- RCBTB2 | c.235G>A p.G79R | Missense Mutation (SNP) | VAF 77/120 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- RELN | c.9764G>A p.G3255D | Missense Mutation (SNP) | VAF 176/705 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- RELN | c.2621C>A p.T874N | Missense Mutation (SNP) | VAF 125/509 reads (25%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- RLF | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 148/364 reads (41%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- RNF17 | c.1445G>A p.R482Q | Missense Mutation (SNP) | VAF 15/144 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ROBO1 | c.3583C>G p.P1195A | Missense Mutation (SNP) | VAF 100/267 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- RPL5 | c.23_25delinsTT p.K8Ifs*11 | Frame Shift Del (DEL) | VAF 71/236 reads (30%) | called by pindel, varscan2*
- SAMM50 | c.422G>A p.G141D | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SCN10A | c.2378del p.I793Tfs*17 | Frame Shift Del (DEL) | VAF 94/257 reads (37%) | called by mutect2, pindel, varscan2
- SLC35F2 | c.1046C>A p.P349Q | Missense Mutation (SNP) | VAF 59/70 reads (84%) | SIFT tolerated (0.27); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLC6A17 | c.299del p.V100Gfs*7 | Frame Shift Del (DEL) | VAF 64/167 reads (38%) | called by mutect2, pindel, varscan2
- SNTA1 | c.1139T>C p.L380P | Missense Mutation (SNP) | VAF 138/471 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SYNJ1 | c.4247C>T p.P1416L | Missense Mutation (SNP) | VAF 89/196 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- SYTL2 | c.1092G>C p.L364F | Missense Mutation (SNP) | VAF 105/290 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- TMEM121B | c.272C>T p.P91L | Missense Mutation (SNP) | VAF 89/215 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- TMEM132C | c.3095G>A p.G1032E | Missense Mutation (SNP) | VAF 83/203 reads (41%) | SIFT tolerated (0.79); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TOPAZ1 | c.2512G>A p.G838S | Missense Mutation (SNP) | VAF 103/219 reads (47%) | SIFT tolerated (0.28); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- TTBK2 | c.98G>A p.G33E | Missense Mutation (SNP) | VAF 115/263 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTK | c.2310T>C p.C770= | Splice Region (SNP) | VAF 28/69 reads (41%) | called by muse, mutect2, varscan2
- UBAP2 | c.1094C>T p.P365L | Missense Mutation (SNP) | VAF 65/84 reads (77%) | SIFT tolerated (0.09); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- UBN1 | c.1384_1385del p.K462Vfs*33 | Frame Shift Del (DEL) | VAF 65/227 reads (29%) | called by mutect2, pindel, varscan2
- UNC80 | c.4039C>T p.Q1347* | Nonsense Mutation (SNP) | VAF 79/227 reads (35%) | called by muse, mutect2, varscan2
- WDR27 | c.1119_1122del p.L373Ffs*18 | Frame Shift Del (DEL) | VAF 89/241 reads (37%) | called by mutect2, pindel, varscan2
- ZFPL1 | c.468G>A p.W156* | Nonsense Mutation (SNP) | VAF 107/241 reads (44%) | called by muse, mutect2, varscan2
- ZNF185 | c.746G>T p.G249V | Missense Mutation (SNP) | VAF 100/115 reads (87%) | SIFT deleterious (0.02); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- ZNF200 | c.59G>C p.R20T | Missense Mutation (SNP) | VAF 78/180 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- ZNF562 | c.448G>A p.G150R (on ENST00000453372 / NM_001130032.2; = p.G78R on NM_017656.4) | Missense Mutation (SNP) | VAF 44/165 reads (27%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- ZNF649 | c.188G>A p.G63E | Missense Mutation (SNP) | VAF 67/316 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.562); called by muse, mutect2, varscan2
- ZNF765 | c.314A>G p.E105G | Missense Mutation (SNP) | VAF 39/158 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- ZNF853 | c.1596_1597del p.R533Hfs*146 | Frame Shift Del (DEL) | VAF 121/602 reads (20%) | called by mutect2, pindel, varscan2
- ABCA7 | c.2325C>T p.C775= | Silent (SNP) | VAF 14/77 reads (18%) | catalogued as rs771423478; called by muse, mutect2, varscan2
- ADAMTS7 | c.2340G>T p.T780= | Silent (SNP) | VAF 201/540 reads (37%) | catalogued as COSV101182994; called by muse, mutect2, varscan2
- ADGRF3 | c.2271C>T p.V757= (on ENST00000311519 / NM_001145168.1; = p.V558= on NM_153835.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 193/486 reads (40%) | called by muse, mutect2, varscan2
- ANKRD24 | c.1611C>T p.T537= | Silent (SNP) | VAF 169/570 reads (30%) | called by muse, mutect2, varscan2
- AP5Z1 | c.1650C>T p.A550= | Silent (SNP) | VAF 78/264 reads (30%) | called by muse, mutect2, varscan2
- ARHGEF12 | c.684C>T p.N228= | Silent (SNP) | VAF 98/133 reads (74%) | called by muse, mutect2, varscan2
- ARNT | c.306G>A p.R102= | Silent (SNP) | VAF 104/233 reads (45%) | called by muse, mutect2, varscan2
- ASIC1 | c.1023G>A p.Q341= | Silent (SNP) | VAF 104/305 reads (34%) | called by muse, mutect2, varscan2
- ASL | c.618C>T p.G206= | Silent (SNP) | VAF 201/715 reads (28%) | called by muse, mutect2, varscan2
- BEST1 | c.199C>T p.L67= | Silent (SNP) | VAF 88/290 reads (30%) | catalogued as COSV100077436; called by muse, varscan2
- CELSR3 | c.6423G>A p.Q2141= | Silent (SNP) | VAF 53/110 reads (48%) | called by muse, mutect2, varscan2
- DLGAP3 | c.2166C>T p.A722= | Silent (SNP) | VAF 98/243 reads (40%) | catalogued as rs764770295; called by muse, mutect2, varscan2
- FAM172A | c.178C>T p.L60= | Silent (SNP) | VAF 41/112 reads (37%) | catalogued as COSV67936404; called by muse, mutect2, varscan2
- GNAS | c.1410C>T p.A470= | Silent (SNP) | VAF 149/536 reads (28%) | called by muse, mutect2, varscan2
- GNPTAB | c.1908G>A p.R636= | Silent (SNP) | VAF 158/363 reads (44%) | catalogued as COSV100172159; called by muse, mutect2, varscan2
- GRIK1 | c.414C>A p.P138= | Silent (SNP) | VAF 154/493 reads (31%) | called by muse, mutect2, varscan2
- GSG1L | c.117C>T p.V39= | Silent (SNP) | VAF 125/294 reads (43%) | called by muse, mutect2, varscan2
- HMGB2 | c.24G>A p.K8= | Silent (SNP) | VAF 66/132 reads (50%) | called by muse, mutect2, varscan2
- HMGB4 | c.186C>T p.A62= | Silent (SNP) | VAF 121/309 reads (39%) | called by muse, mutect2, varscan2
- IPO11 | c.2868C>T p.L956= | Silent (SNP) | VAF 64/158 reads (41%) | called by muse, mutect2, varscan2
- KANK3 | c.1839G>A p.A613= | Silent (SNP) | VAF 198/730 reads (27%) | catalogued as rs368061289, COSV58360783; called by muse, varscan2
- KLK12 | c.564C>T p.G188= | Silent (SNP) | VAF 220/802 reads (27%) | catalogued as rs145723658; called by muse, mutect2, varscan2
- LAMB1 | c.2218C>T p.L740= | Silent (SNP) | VAF 177/606 reads (29%) | called by muse, mutect2, varscan2
- LHX8 | c.789C>T p.G263= | Silent (SNP) | VAF 115/360 reads (32%) | catalogued as rs1210926908; called by muse, mutect2, varscan2
- LRIT3 | c.1215C>G p.P405= | Silent (SNP) | VAF 132/320 reads (41%) | called by muse, mutect2, varscan2
- LRRC8A | c.2373C>T p.F791= | Silent (SNP) | VAF 104/262 reads (40%) | catalogued as COSV99396969; called by muse, mutect2, varscan2
- MAST1 | c.2382C>T p.A794= | Silent (SNP) | VAF 48/147 reads (33%) | called by muse, mutect2
- MIGA2 | c.813C>T p.P271= | Silent (SNP) | VAF 70/225 reads (31%) | called by muse, mutect2, varscan2
- MTFR1 | c.576G>A p.P192= | Silent (SNP) | VAF 64/168 reads (38%) | catalogued as rs770323230; called by muse, mutect2, varscan2
- NVL | c.1755C>T p.A585= | Silent (SNP) | VAF 20/396 reads (5%) | called by muse, mutect2
- OPLAH | c.864G>A p.S288= | Silent (SNP) | VAF 111/289 reads (38%) | catalogued as rs1554759938, COSV70679130; called by muse, mutect2, varscan2
- OR8J3 | c.838T>C p.L280= | Silent (SNP) | VAF 51/147 reads (35%) | called by muse, mutect2, varscan2
- PLCD1 | c.1770G>A p.Q590= | Silent (SNP) | VAF 253/607 reads (42%) | catalogued as COSV99378743; called by muse, mutect2, varscan2
- PLEKHG3 | c.2052G>A p.E684= (on ENST00000394691; = p.E740= on NM_001308147.2) | Silent (SNP) | VAF 74/212 reads (35%) | catalogued as rs761752996; called by muse, mutect2, varscan2
- PLXNB1 | c.891C>T p.F297= | Silent (SNP) | VAF 148/351 reads (42%) | catalogued as COSV56488306; called by muse, mutect2, varscan2
- PPFIA3 | c.69G>A p.E23= | Silent (SNP) | VAF 115/442 reads (26%) | catalogued as rs751654086; called by muse, mutect2, varscan2
- PRSS36 | c.543C>A p.V181= | Silent (SNP) | VAF 19/329 reads (6%) | called by muse, mutect2
- RBFOX1 | c.573C>A p.A191= | Silent (SNP) | VAF 40/105 reads (38%) | called by muse, mutect2, varscan2
- RELN | c.2511T>A p.I837= | Silent (SNP) | VAF 98/371 reads (26%) | called by muse, mutect2, varscan2
- SCN7A | c.1554C>T p.N518= | Silent (SNP) | VAF 60/131 reads (46%) | catalogued as rs561659004, COSV69273001; called by muse, mutect2, varscan2
- SIPA1L3 | c.3849C>T p.S1283= | Silent (SNP) | VAF 69/244 reads (28%) | catalogued as rs761002860, COSV55924999; called by muse, mutect2, varscan2
- SLC44A2 | c.1377C>T p.F459= | Silent (SNP) | VAF 118/418 reads (28%) | catalogued as COSV59834966; called by muse, mutect2, varscan2
- SON | c.2874A>C p.L958= | Silent (SNP) | VAF 96/255 reads (38%) | called by muse, mutect2, varscan2
- SPTB | c.2862C>T p.L954= | Silent (SNP) | VAF 178/410 reads (43%) | catalogued as rs1369534604, COSV67632690; called by muse, mutect2, varscan2
- THSD1 | c.834C>T p.A278= | Silent (SNP) | VAF 68/114 reads (60%) | catalogued as rs140001898; called by muse, mutect2, varscan2
- TRMT6 | c.567C>T p.A189= | Silent (SNP) | VAF 66/245 reads (27%) | catalogued as rs759809544; called by muse, mutect2, varscan2
- TTC6 | c.2556T>C p.D852= | Silent (SNP) | VAF 100/226 reads (44%) | catalogued as rs1363199747; called by muse, mutect2, varscan2
- UBC | c.165C>T p.T55= | Silent (SNP) | VAF 204/578 reads (35%) | catalogued as rs1202475986; called by muse, mutect2, varscan2
- USH2A | c.3735A>G p.R1245= | Silent (SNP) | VAF 111/256 reads (43%) | called by muse, mutect2, varscan2
- WDR27 | c.1329C>T p.V443= | Silent (SNP) | VAF 61/149 reads (41%) | called by muse, mutect2, varscan2
- WDR74 | c.141C>T p.A47= | Silent (SNP) | VAF 173/382 reads (45%) | called by muse, mutect2, varscan2
- ZNFX1 | c.4287C>T p.V1429= | Silent (SNP) | VAF 136/551 reads (25%) | called by muse, mutect2, varscan2
- ABCC5 | c.3694+237G>A | Intron (SNP) | VAF 148/418 reads (35%) | catalogued as rs760020200; called by muse, mutect2, varscan2
- AC002511.3 | n.32G>A | RNA (SNP) | VAF 75/259 reads (29%) | catalogued as rs754876517; called by muse, mutect2, varscan2
- AIRE | c.*14G>A | 3'UTR (SNP) | VAF 231/575 reads (40%) | called by muse, mutect2, varscan2
- AL136982.4 | n.984C>A | RNA (SNP) | VAF 369/601 reads (61%) | called by muse, mutect2, varscan2
- ATP8B3 | c.1552+95G>A | Intron (SNP) | VAF 60/227 reads (26%) | called by muse, mutect2, varscan2
- C16orf92 | chr16:30027130 C>T | 3'Flank (SNP) | VAF 51/159 reads (32%) | catalogued as rs1030541298; called by muse, mutect2, varscan2
- C21orf58 | c.445-40C>T | Intron (SNP) | VAF 101/257 reads (39%) | called by muse, mutect2, varscan2
- CAMK2B | c.1226-15C>G | Intron (SNP) | VAF 9/46 reads (20%) | called by muse, mutect2
- CD37 | c.343-174G>A | Intron (SNP) | VAF 59/178 reads (33%) | catalogued as rs1210480550; called by muse, mutect2, varscan2
- COBLL1 | c.344+70C>T | Intron (SNP) | VAF 46/105 reads (44%) | catalogued as rs754831585; called by muse, mutect2, varscan2
- CYP39A1 | c.*10G>C | 3'UTR (SNP) | VAF 26/65 reads (40%) | catalogued as rs1351642807; called by muse, mutect2, varscan2
- DOCK4 | c.2736+3936C>T | Intron (SNP) | VAF 65/213 reads (31%) | called by muse, mutect2, varscan2
- DPYSL2 | chr8:26577111 G>A | 5'Flank (SNP) | VAF 114/223 reads (51%) | catalogued as rs1379654872; called by muse, mutect2, varscan2
- ETNK1 | c.-181C>T | 5'UTR (SNP) | VAF 132/338 reads (39%) | called by muse, mutect2, varscan2
- EXOC7 | c.1930-102G>A | Intron (SNP) | VAF 203/512 reads (40%) | called by muse, mutect2, varscan2
- FAM186B | c.96+57G>A | Intron (SNP) | VAF 62/151 reads (41%) | called by muse, mutect2, varscan2
- FKBP10 | c.1063+167C>T | Intron (SNP) | VAF 23/67 reads (34%) | catalogued as rs1248556782; called by muse, mutect2, varscan2
- FXYD3 | c.97+24C>T | Intron (SNP) | VAF 65/271 reads (24%) | catalogued as rs1568386766; called by muse, mutect2, varscan2
- GSN-AS1 | n.3884C>T | RNA (SNP) | VAF 124/282 reads (44%) | called by muse, mutect2, varscan2
- ICA1 | c.256+758G>T | Intron (SNP) | VAF 40/230 reads (17%) | called by muse, mutect2, varscan2
- INTS6 | c.-22C>T | 5'UTR (SNP) | VAF 123/182 reads (68%) | called by muse, mutect2, varscan2
- KCP | c.577+191C>T | Intron (SNP) | VAF 114/476 reads (24%) | called by muse, mutect2
- LFNG | chr7:2528892 G>A | 3'Flank (SNP) | VAF 27/64 reads (42%) | catalogued as rs562235848, COSV56069254; called by muse, mutect2, varscan2
- LINC00479 | n.492C>T | RNA (SNP) | VAF 90/259 reads (35%) | called by muse, mutect2, varscan2
- LINC00671 | n.625T>C | RNA (SNP) | VAF 34/84 reads (40%) | called by muse, mutect2
- LINC02210-CRHR1 | c.-493+10452G>A | Intron (SNP) | VAF 74/229 reads (32%) | called by muse, mutect2, varscan2
- MICAL1 | c.2305-47G>C | Intron (SNP) | VAF 104/353 reads (29%) | called by muse, mutect2
- MISP3 | c.1069-12C>T | Intron (SNP) | VAF 90/339 reads (27%) | catalogued as rs1323286005; called by muse, mutect2, varscan2
- MRPL20 | chr1:1400161 del GTC | 3'Flank (DEL) | VAF 56/157 reads (36%) | called by mutect2, pindel, varscan2
- Metazoa_SRP | chr15:62246629 C>A | 5'Flank (SNP) | VAF 8/180 reads (4%) | called by muse, mutect2
- NACA | c.71-4128C>T | Intron (SNP) | VAF 51/108 reads (47%) | catalogued as rs1269090297; called by muse, mutect2, varscan2
- NOP9 | c.*2707G>A | 3'UTR (SNP) | VAF 121/261 reads (46%) | catalogued as rs1450829438; called by muse, mutect2, varscan2
- NPIPB1P | n.1064G>C | RNA (SNP) | VAF 220/632 reads (35%) | called by muse, varscan2
- NSMAF | c.59+148G>A | Intron (SNP) | VAF 77/164 reads (47%) | called by muse, mutect2, varscan2
- PDP1 | c.-45+853G>C | Intron (SNP) | VAF 84/224 reads (38%) | called by muse, mutect2, varscan2
- POGLUT1 | c.85+29C>T | Intron (SNP) | VAF 105/333 reads (32%) | catalogued as rs1373282242; called by muse, mutect2, varscan2
- PPP2R3C | c.59-370C>T | Intron (SNP) | VAF 91/243 reads (37%) | catalogued as rs1048382782; called by muse, mutect2, varscan2
- PSAT1 | c.-52C>T | 5'UTR (SNP) | VAF 220/492 reads (45%) | called by muse, mutect2
- RABL2A | c.137+38G>A | Intron (SNP) | VAF 171/483 reads (35%) | catalogued as rs943612159; called by muse, mutect2, varscan2
- RNU7-115P | chr17:64821949 C>T | 3'Flank (SNP) | VAF 304/724 reads (42%) | catalogued as rs755561023; called by muse, varscan2
- RPL27A | c.-1C>G | 5'UTR (SNP) | VAF 70/159 reads (44%) | catalogued as rs754250435; called by muse, mutect2, varscan2
- RPS21 | c.114+83G>A | Intron (SNP) | VAF 45/158 reads (28%) | catalogued as rs1422411816; called by muse, mutect2, varscan2
- SLAMF8 | chr1:159837978 C>A | 3'Flank (SNP) | VAF 63/253 reads (25%) | called by muse, mutect2, varscan2
- SPAG6 | c.-32G>C | 5'UTR (SNP) | VAF 60/84 reads (71%) | called by muse, mutect2, varscan2
- SPINK5 | c.475-411T>C | Intron (SNP) | VAF 71/157 reads (45%) | called by muse, mutect2, varscan2
- TCOF1 | c.3517+41G>A | Intron (SNP) | VAF 41/107 reads (38%) | called by muse, mutect2, varscan2
- TIMM44 | c.1039-36G>A | Intron (SNP) | VAF 68/247 reads (28%) | catalogued as rs373618431; called by muse, mutect2, varscan2
- TP53I13 | c.73-46G>A | Intron (SNP) | VAF 165/461 reads (36%) | called by muse, mutect2, varscan2
- WDR49 | c.487-6642A>C | Intron (SNP) | VAF 39/118 reads (33%) | catalogued as COSV100393346; called by muse, mutect2, varscan2
- ZSWIM4 | chr19:13836439 C>T | 3'Flank (SNP) | VAF 73/215 reads (34%) | catalogued as rs759235923; called by muse, mutect2, varscan2
